Surgical pathology report (de-identified scan), TCGA case TCGA-GD-A2C5, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GD-A2C5-01A (Primary Tumor).

[page 1 of 4]
Final Pathologic Diagnosis:

A. Ureter, left distal, biopsy for frozen section examination of margin:
No pathologic change.
The frozen section diagnosis is confirmed.

B. Ureter, right distal, biopsy for frozen section examination of margin:
No pathologic change.
The frozen section diagnosis is confirmed.

C. Urinary bladder, anterior exenteration:

Tumor histologic type: Urothelial carcinoma

Variant histology (%): No

Tumor size: greatest dimension: 29 mm

Additional dimensions: 20 x 10 mm

Grade (WHO 2004): High

Tumor configuration: Papillary and nodular/infiltrative

Associated epithelial lesions: Urothelial carcinoma in situ

Microscopic tumor extension: Tumor superficially invades perivesical soft tissue

Lymph-vascular invasion: Present

Margins:

Urethral: Negative

Ureteral: Negative (parts A and B)

Paravesical soft tissue: Negative

Other (specify): Vaginal mucosal margins are negative

Additional pathologic findings: Transurethral resection wound

Paravesical lymph nodes (number positive/total number): 0/1

All lymph nodes (number positive/total number): 2/17

Size of largest lymph node metastasis: 9 mm; right pelvic lymph nodes

Extranodal extension (location): No

Pathologic stage pT3a pN2 pM-Not applicable

Uterus, uterine cervix, bilateral fallopian tubes and ovaries, anterior exenteration:

Uterine cervix with no pathologic change.

Inactive endometrium with no pathologic change.

Fallopian tubes with no pathologic change.

Benign paratubal cysts.

Atrophic ovaries with corpora albicantia.

Vagina (52 x 38 mm), partial resection:

Negative for malignancy.

D. Lymph nodes (7), right pelvic, excision:

One lymph node positive for metastatic carcinoma (1/7).

ICD-0-3

Carcinoma, Urothelial, NOS
8/20/3

Site: bladder, NOS C67.9

6/1/11

[page 2 of 4]
E. Lymph nodes (9), left pelvic, excision:
One lymph node positive for metastatic carcinoma (1/9).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA: Left ureter:

No evidence of malignancy.

FSB: Right ureter:

No evidence of malignancy.

F/S TAT: 12.5 mins. each

Gross Description:

Received are five containers labeled with the patient's name. The first two containers are received without formalin for frozen section. The remaining three containers are received with formalin.

The first is labeled "A, left distal ureter FS" and contains a full thickness cross section of apparent ureter measuring 0.4 cm in diameter and 0.3 cm in length with a small amount of associated fat. The specimen is submitted in toto for frozen section diagnosis with the residue now resubmitted for permanent section in cassette A1.

The second container is labeled "B, right distal ureter" and contains a short segment of apparent ureter measuring 1.2 cm in length with an average diameter of 0.6 cm. One aspect is tagged with a suture. A representative section is submitted for frozen section diagnosis with the residue now resubmitted for permanent section in cassette B1. The remaining tissue is now serially sectioned and submitted entirely in cassette B2.

The third container is labeled "anterior exenteration" and contains an anterior exenteration specimen including the urinary bladder, which measures 5.5 x 4.5 x 3.2 cm, the uterus which measures 7.2 x 4.5 x 3.0 cm and an excision of vaginal cuff surrounding the cervix measuring 5.2 x 3.8 cm in area. The soft tissue surfaces overlying the bladder are inked black. The irregular resection margins surrounding the vaginal cuff are inked blue. The specimen is opened longitudinally revealing a papillary tumor involving the approximate midline trigone area of the bladder mucosa, measuring 1.4 x 0.9 x 0.8 cm. Adjacent to the right of the tumor is an area of previous fulguration measuring 2.0 x 1.9 cm in area. Combined, these two areas measure 2.9 cm in greatest dimension. Sectioning of this area reveals gross invasion to a depth of 1.0 cm at a distance of 0.2 cm from the inked posterior soft tissue surface. The mass does not grossly appear to invade the uterine cervix or other structures.

[page 3 of 4]
Representative sections of the bladder are submitted in the following manner:

- C1 urethral margin;
- C2 12 to 3 o' clock vaginal cuff mucosa margin;
- C3 3 to 6 o' clock vaginal cuff mucosa margin;
- C4 6 to 9 o' clock vaginal cuff mucosa margin;
- C5 9 to 12 o' clock vaginal cuff mucosa margin;
- C6-7 relationship of mass to vaginal mucosa;
- C8-11 mass with deepest invasion in right posterior soft tissue;
- C12 bladder dome;
- C13 left bladder wall.

The uterine ectocervix is pink-tan, smooth and glistening with no grossly suspicious lesions. The endocervix is pink-tan and velvety with a few small cystic spaces on the cut surface containing mucoid material. Sectioning of the myometrium reveals an average endometrial thickness of 0.3 cm and an average myometrial thickness of 1.0 cm. There are no grossly suspicious endometrial or myometrial lesions. The left ovary measures 1.5 x 1.0 x 0.6 cm and has a cerebriform outer surface. The attached segment of fallopian tube includes the fimbriated end and measures 3.0 cm with an average diameter of 0.6 cm. Sectioning of both the left adnexal structures reveals no grossly suspicious lesions. The ovarian cut surface is white-tan and homogeneous. The right adnexal structures include a segment of fallopian tube measuring 3.5 cm in length with a diameter that tapers from 0.6 to 0.8 cm and an occluded fimbriated end. The right ovary is not grossly identifiable. Sectioning reveals no grossly suspicious lesions.

Representative sections from the uterus are submitted in the following manner:

- C14 anterior cervix;
- C15 posterior cervix;
- C16 anterior full thickness endomyometrium;
- C17 posterior full thickness endomyometrium;
- C18 left adnexal structures;
- C19 right adnexal structures.

The paravesical fat is trimmed and subjected to chemical clearing and Carnoy's solution prior to exhaustive lymph node search, which reveals a few small possible lymph nodes ranging in size from 0.2 to 0.3 cm in greatest dimension. The nodes are submitted entirely in cassettes C20 and C21.

The fourth container is labeled "D, right pelvic nodes" and contains two strips of yellow-tan lobulated fatty tissue measuring 4.2 x 1.5 x 1.0 cm and 3.5 x 1.5 x 0.6 cm. The specimen is subjected to chemical clearing in Carnoy's solution prior to lymph node search, which reveals two gross lymph nodes measuring 1.4 and 3.5 cm in greatest dimension.

The specimen is submitted entirely in the following manner:

[page 4 of 4]
- D1 largest lymph node bisected;
- D2 one lymph node bisected;
- D3-4 remaining fatty tissue.

The fifth container is labeled "E, left pelvic lymph nodes" and contains a single fragment of yellow-tan lobulated fatty tissue measuring 4.5 x 1.8 x 1.8 cm. The specimen is subjected to chemical clearing with Carnoy's solution prior to exhaustive lymph node search, which reveals three grossly identifiable lymph nodes ranging in size from 0.4 to 2.5 cm in greatest dimension.

The specimen is submitted entirely in the following manner:

- E1 two whole small lymph nodes;
- E2-3 one large lymph node bisected;
- E4-5 remaining fatty tissue.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Taken:

END OF REPORT

Source: NCI Genomic Data Commons file 7858984b-6dba-45a6-808e-3fc98fc6fb88 (TCGA-GD-A2C5.1522A38C-0867-4275-AB24-FF21B8E988B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).